CCDI case PBCJKS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/897bf5c1-90ef-4d0e-9879-a9acbb709677

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,537 days).

Biospecimens (3 samples)
- Sample 0DT9N2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT9NF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DT9NK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
